Somatic mutation profile of tumor specimen 0DIW7P from CCDI case PBBUYE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.2 years (1,901 days).
Specimen 0DIW7P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f5a5f39-7469-4301-a3b1-2732412febbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIW61 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8163c96-5482-4628-969c-1615a6402eaf

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK5RAP2 | c.5602C>T p.R1868W | Missense Mutation (SNP) | VAF 121/720 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141534162; called by muse, varscan2
- FSIP2 | c.5335C>T p.P1779S | Missense Mutation (SNP) | VAF 220/1028 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58080342; called by muse, varscan2
- ITGB1BP2 | c.64+41G>T | Intron (SNP) | VAF 112/432 reads (26%) | called by muse, varscan2
